Somatic mutation profile of tumor specimen TARGET-10-PAPCVI-09A (aliquot TARGET-10-PAPCVI-09A-01D) from TARGET case TARGET-10-PAPCVI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,541 days).
Specimen TARGET-10-PAPCVI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e733e0a-6d87-4343-ae5a-4d368dd1a309.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPCVI-10A (Blood Derived Normal), aliquot TARGET-10-PAPCVI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b24c384-d60b-4baa-b0ed-36ac06860ce1

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 1, Nonsense Mutation 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKS1A | c.952A>C p.T318P | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.091); catalogued as rs767137276; called by muse, mutect2, varscan2
- BPIFB3 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.163); catalogued as rs753724962, COSV64957251; called by muse, mutect2
- DLX4 | c.284-6C>T | Splice Region (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99537678; called by muse, mutect2, varscan2
- IGHV1-69D | chr14:106762091 GTCTCTCGCACAGTAA>CCACCT | Missense Mutation (DEL) | VAF 32/84 reads (38%) | called by pindel, varscan2*
- IGLV4-69 | chr22:22031467 CATTCACACAGTGACACAGG>TCA | Missense Mutation (DEL) | VAF 21/93 reads (23%) | called by pindel, varscan2*
- NXPE2 | c.1273G>C p.V425L | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VWF | c.6068C>A p.T2023K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CLEC19A | c.285C>T p.L95= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs1340449619; called by muse, mutect2, varscan2
- IGHV1-58 | c.321C>T p.S107= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs911072372; called by muse, varscan2
- OAS1 | c.624C>A p.L208= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- UGT2B4 | c.1443C>T p.H481= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs547579888, COSV59315571; called by muse, mutect2, varscan2
- LIPG | c.*115C>A | 3'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- TMTC2 | c.1869+124C>T | Intron (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
